TCGA case TCGA-VR-AA4G — Esophageal Carcinoma (TCGA-ESCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Esophagus; Tissue source site: Barretos Cancer Hospital. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/df5bd25c-d70b-4126-89cb-6c838044ae3b

Demographics
Sex at birth: female; Race: white; Country of residence at enrollment: Brazil; Age at index: 51 years; Vital status: Alive; Country of birth: Brazil.

Diagnoses (1)
1. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; ICD-10 code: C15.4; Tissue or organ of origin: Middle third of esophagus; Site of resection or biopsy: Esophagus, NOS; Classification of tumor: primary; Age at diagnosis: 51.8 years (18,909 days); Year of diagnosis: 2013; Method of diagnosis: Biopsy; AJCC staging edition: 7th; AJCC clinical T: T2; AJCC clinical N: N2; AJCC clinical M: M0; AJCC clinical stage: Stage IIIA; AJCC pathologic T: T2; AJCC pathologic N: N2; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 549 days (1.5 years); Cancer detection method: Symptomatic; Esophageal columnar dysplasia degree: Negative/ No Dysplasia; Esophageal columnar metaplasia present: No; Goblet cells columnar mucosa present: No; Sites of involvement: Esophagus, Middle Third.
   Pathology details: Consistent pathology review: Yes; Lymph node involvement: Positive; Lymph nodes positive: 1; Lymph nodes tested: 25.
   Treatment given: Treatment type: Surgery, NOS.
   Recorded as not given: Chemotherapy, preoperative; adjuvant Pharmaceutical Therapy, NOS; Radiation Therapy, NOS, preoperative; adjuvant Radiation Therapy, NOS.

Follow-up (5 entries)
- Days to follow up: 366 days (1.0 years); Disease response: Tumor Free.
- Days to follow up: 458 days (1.3 years); Disease response: Tumor Free.
- Days to follow up: 519 days (1.4 years); Disease response: Tumor Free.
- Days to follow up: 549 days (1.5 years); Disease response: Tumor Free.
- Karnofsky performance status: 90; ECOG performance status: 1.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 69 kg; Height: 159 cm; BMI: 27.3.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Pack years smoked: 10; Age at onset: 12.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-VR-AA4G-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 90 mg.
  Slide TCGA-VR-AA4G-01A-01-TS1: Section location: Top; Percent tumor cells: 50; Percent tumor nuclei: 80; Percent normal cells: 10; Percent necrosis: 0; Percent stromal cells: 40; Percent lymphocyte infiltration: 4; Percent monocyte infiltration: 8; Percent neutrophil infiltration: 1.
- Sample TCGA-VR-AA4G-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-VR-AA4G-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; Cancer procurement state province: Sao Paulo; Cancer procurement city: Barretos; History neoadjuvant treatment: No; Tumor status: Tumor free; Tobacco smoking history indicator: 4; Alcohol history documented: No; History reflux disease indicator: No; History hpylori infection indicator: Never; History barretts esophageal indicator: No; New tumor event diagnosis indicator: No.
- Primary pathology: Esophageal tumor location centered: Mid; Histologic diagnosis: Esophagus Squamous Cell Carcinoma; Esoph non CA degree of dysplasia: Negative/no dysplasia; Method initial path diagnosis: Endoscopic Biopsy; Lymph node sprd radiograph evidence: Yes; Lymph nodes examined: Yes; Patient to undergo surgery: Surgery already performed.
- Primary pathology, Esophageal tumor involvement sites: Esophageal tumor location involved: Mid.
- Follow-up form 1: Lost to follow-up: No; Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response; Treatment outcome at TCGA followup: Complete Response; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 549 days; disease-specific survival: no event (censored), 549 days; disease-free interval: no event (censored), 549 days; progression-free interval: no event (censored), 549 days.
